Surgical pathology report (de-identified scan), TCGA case TCGA-BB-A5HY, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-BB-A5HY-01A (Primary Tumor).

[page 1 of 2]
SURG PATH REPORT

ICD-03
Carcinoma, squamous cell NOS
8070/3

Site: Hypopharynx NOS
C13.9
9/21/28/13

FINAL DIAGNOSIS ----- Pathologist:

1) INFERIOR PHARYNGEAL MARGIN (EXCISION): SQUAMOUS EPITHELIUM AND SUBMUCOSA, NEGATIVE FOR TUMOR AND DYSPLASIA.

2) PARATHYROID (EXCISION): PARATHYROID TISSUE (7 MG).

3) SUPERIOR POSTERIOR PHARYNGEAL MARGIN (EXCISION): FRAGMENTS OF SQUAMOUS EPITHELIUM AND SUBMUCOSA, NEGATIVE FOR TUMOR AND DYSPLASIA.

4) LEFT NECK DISSECTION LEVEL 2-5 (DISSECTION): METASTATIC POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA IN ONE (1) LEVEL 2 LYMPH NODE AND TWO (2) LEVEL 3 LYMPH NODES. TOTAL: THREE (3) OF TWENTY-FOUR (24) LYMPH NODES (3/24) POSITIVE FOR METASTATIC CARCINOMA. EXTRACAPSULAR EXTENSION IS PRESENT. THE LARGEST FOCUS OF CARCINOMA IS 5 CM IN GREATEST DIMENSION (LEVEL 2).

5) POSTERIOR PHARYNGEAL WALL (EXCISION): PHARYNGEAL WALL AND ATTACHED SOFT TISSUE, NEGATIVE FOR TUMOR AND DYSPLASIA.

6) LARYNX & PYRIFORM SINUS (RESECTION):

SPECIMEN TYPE:

TOTAL LARYNGOPHARYNGECTOMY AND LEFT HEMITHYROIDECTOMY

TUMOR SITE:

HYPOPHARYNX: LEFT PYRIFORM SINUS

TUMOR SIZE:

GREATEST DIMENSION: 5.5 CM

HISTOLOGIC TYPE:

SQUAMOUS CELL CARCINOMA, CONVENTIONAL

HISTOLOGIC GRADE:

G3: POORLY DIFFERENTIATED

EXTENT OF INVASION (7th Edition AJCC):

PRIMARY TUMOR (pT): Hypopharynx

pT3: TUMOR MEASURES MORE THAN 4 CM IN GREATEST DIMENSION OR WITH FIXATION OF HEMILARYNX

REGIONAL LYMPH NODES (pN):

pN2b: METASTASIS IN MULTIPLE IPSILATERAL LYMPH NODES, MORE THAN 3 CM BUT NOT MORE THAN 6 CM IN GREATEST DIMENSION

EXTRACAPSULAR EXTENSION OF NODAL TUMOR: PRESENT

DISTANT METASTASIS (pM):

pMx: CANNOT BE ASSESSED

MARGINS:

MARGINS UNINVOLVED BY TUMOR

DISTANCE OF TUMOR FROM CLOSEST MARGIN: 0.5 MM TO LEFT LATERAL SOFT TISSUE MARGIN

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION:

INDETERMINATE

*** Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB RESULTS PERFORMED AT:

[page 2 of 2]
PERINEURAL INVASION:
ABSENT

ADDITIONAL PATHOLOGIC FINDINGS:
CARCINOMA IN SITU OVERLYING TUMOR
HISTOLOGICALLY UNREMARKABLE LEFT THYROID

NOTE: has reviewed select slides and concurs with the
diagnosis.

***** End of Diagnosis *****

Clinical History:

*** Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB RESULTS PERFORMED AT:

Page 2 of 2

Case #	11/24/13	Yes	No
Staging Discrepancy			/
Pathologic Malignancy History			/
Metastatic/Secondary Tumor History			/
Site of Care	RE	DISQUALIFIED	DISQUALIFIED
Reviewed Initials	RE	Date Reviewed	11/27/13

Source: NCI Genomic Data Commons file ef8ee33e-b732-4bfe-a034-7775e0a9c9cf (TCGA-BB-A5HY.69120AE2-5E0A-40FA-B465-B2371F4A08B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).